Somatic mutation profile of tumor specimen 0DTREI from CCDI case PBCKDM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.6 years (6,061 days).
Specimen 0DTREI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98dca720-c330-4f3f-86e9-7bbb0bb2b6e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTREP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bac08b0-faaf-4ba1-94dd-168cfde591a1

The open-access MAF lists 28 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 3, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 200/496 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 446/497 reads (90%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ATRX | c.4510C>T p.R1504* | Nonsense Mutation (SNP) | VAF 331/808 reads (41%) | catalogued as COSV64872902; called by muse, mutect2, varscan2
- BCAM | c.1144G>A p.V382M | Missense Mutation (SNP) | VAF 172/393 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs200516188; called by muse, mutect2, varscan2
- C3orf22 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 224/555 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.06); catalogued as rs373190783; called by muse, mutect2, varscan2
- DNAH9 | c.3577G>A p.E1193K | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.607); catalogued as COSV52331690; called by muse, mutect2, varscan2
- IL4R | c.245C>T p.A82V | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs750194290, COSV50165731; called by muse, mutect2
- MYH2 | c.3517C>T p.R1173W | Missense Mutation (SNP) | VAF 837/958 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767243766, COSV55434229; called by muse, mutect2, varscan2
- RIPK4 | c.1595G>A p.R532Q (on ENST00000352483; = p.R484Q on NM_020639.3) | Missense Mutation (SNP) | VAF 149/559 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.271); catalogued as rs777150995, COSV60189588; called by muse, mutect2, varscan2
- SLC26A3 | c.685A>G p.I229V | Missense Mutation (SNP) | VAF 382/1119 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs762953026; called by muse, mutect2, varscan2
- ZCCHC24 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 136/448 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs775068470; called by muse, mutect2, varscan2
- ATP7A | c.4006A>T p.N1336Y | Missense Mutation (SNP) | VAF 162/450 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CCNL2 | c.1097_1100dup p.D368Gfs*22 | Frame Shift Ins (INS) | VAF 121/546 reads (22%) | called by mutect2, varscan2
- DSCAML1 | c.6196C>T p.P2066S (on ENST00000321322; = p.P2006S on NM_020693.4) | Missense Mutation (SNP) | VAF 413/452 reads (91%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- EFHC2 | c.1123T>A p.S375T | Missense Mutation (SNP) | VAF 246/690 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MLLT3 | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 401/931 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TSC22D2 | c.1625G>A p.S542N | Missense Mutation (SNP) | VAF 30/910 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2
- ABCC5 | c.2196C>G p.L732= | Silent (SNP) | VAF 329/817 reads (40%) | called by muse, mutect2, varscan2
- ANKRD36B | c.1134A>C p.T378= | Silent (SNP) | VAF 610/1747 reads (35%) | called by muse, mutect2, varscan2
- HGSNAT | c.1347C>T p.D449= | Silent (SNP) | VAF 214/485 reads (44%) | catalogued as rs752420375; ClinVar: likely benign; called by muse, mutect2, varscan2
- MADCAM1 | c.960G>A p.A320= | Silent (SNP) | VAF 244/554 reads (44%) | catalogued as rs770550961; called by muse, mutect2, varscan2
- MS4A4A | c.570C>G p.L190= | Silent (SNP) | VAF 713/1059 reads (67%) | catalogued as COSV59700262; called by muse, mutect2, varscan2
- MYH14 | c.3234T>C p.D1078= | Silent (SNP) | VAF 192/470 reads (41%) | called by muse, mutect2, varscan2
- SLC8A2 | c.1332C>T p.Y444= | Silent (SNP) | VAF 29/280 reads (10%) | catalogued as rs1359478201; called by muse, mutect2, varscan2
- DDX27 | c.1366+98C>T | Intron (SNP) | VAF 34/88 reads (39%) | catalogued as rs145336910; called by muse, mutect2, varscan2
- GOLIM4 | c.600+64A>T | Intron (SNP) | VAF 24/598 reads (4%) | called by muse, mutect2
- IL12RB1 | c.*80C>A | 3'UTR (SNP) | VAF 102/200 reads (51%) | called by muse, mutect2
- OBSCN | c.18662-2449C>T | Intron (SNP) | VAF 323/746 reads (43%) | catalogued as COSV99478371; called by muse, mutect2, varscan2
